Gene-level copy-number profile of tumor specimen TCGA-85-A4JC-01A from TCGA case TCGA-85-A4JC, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.7 years (30,942 days).
Specimen TCGA-85-A4JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.10ce51bd-d718-493f-b201-af407d89b923.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A4JC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39966935-030e-473f-9012-acbcdcb6f1cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 7; copy number 2: 30,452; copy number 3: 9,236; copy number 4: 16,561; copy number 6: 2,890; copy number 8: 27; copy number 9: 637.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A4JC-01A-11D-A256-01): tumor purity 0.48, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,528,861–59,703,703, 2 genes: NDUFB4P2, MIR582.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,554 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,491,636–47,191,044, 284 genes, copy number 6 (broad region; genes not listed).
- chr2:36,299,388–69,674,349, 551 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–9 (broad region; genes not listed).
- chr15:95,990,582–101,933,350, 147 genes, copy number 6–8 (broad region; genes not listed).
- chr20:16,982,831–19,212,164, 61 genes, copy number 6 (broad region; genes not listed).
- chr20:19,212,852–19,213,477, 1 gene, copy number 6: AL136090.1.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
